Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A43N, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A43N-01A (Primary Tumor).

[page 1 of 4]
Sample

Gender: Male

DOB:

Race: White

Report Date:

Pathology Report:

1CD-0-3

Carcinoma, urothelial, NOS 8/20/3
CACF Site: bladder, wall, posterior C67.4
Path: bladder, NOS C67.9

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Left pelvic lymph nodes; dissection:
- Twenty lymph nodes, no tumor (0/20).

B. Right pelvic lymph nodes; dissection:
- Thirteen lymph nodes, no tumor (0/13).

C. Urinary bladder, prostate, seminal vesicles, and vas deferens;
cystoprostatectomy:
- Bladder with invasive urothelial carcinoma with focal squamous
differentiation, see pathologic parameters.
- Tumor invades the bladder muscular wall and with focal microscopic
extravesicular soft tissue extension.
- Prostatic urethra with focal urothelial carcinoma in situ, with extension
to prostatic ducts.
- Urethral, ureteral and soft tissue margins, free of tumor.

D. Right distal ureter; excision:
- Portion of ureter, no tumor.

E. Bilateral vas deferens; excision:
- Vas deferens, no tumor.

Diagnostic Discrepancy		
IPSA Discrepancy		
Qual/Synchronous: Primary Noted		
Reviewed Initial	8/17/12	

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Invasive urothelial carcinoma with focal squamous differentiation (10%). < 10% per TSS 9/7/12. lw
2. Grade of tumor: High grade.
3. Depth of invasion: Microscopic extravesicular soft tissue extension (slide C8).
4. Tumor distribution: Solitary; 4.0 cm; right lateral, anterior and posterior wall.
5. Ureteral margins: Negative for tumor.

[page 2 of 4]
6. Distal urethral margin: Negative for tumor.
7. Soft tissue margin or serosa: Negative for tumor.
8. Lymph nodes: Negative for tumor (0/33).
9. pTNM: pT3a,N0,MX.

Effective _____ is Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

xx

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow
Electronically Signed Out by _____

Clinical History:

The patient is a _____ year-old male with high grade urothelial carcinoma of the bladder undergoing cystoprostatectomy and ileoconduit.

Specimens Received:

- A: Left pelvic lymph nodes
- B: Right pelvic lymph nodes
- C: Bladder, prostate, seminal vesicles, and vas deferens
- D: Right distal ureter
- E: Bilateral vas deferens

Gross Description:

The specimens are received in five containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "left pelvic lymph nodes". Received fresh and placed in formalin is an aggregate of tan-yellow tissue measuring 6.0 x 4.5 x 2.0 cm. Twenty-two lymph nodes are identified ranging in greatest dimension from 0.2-2.4 cm. The lymph nodes are submitted as follows:

- A1: Largest lymph node bisected.
- A2: One lymph node bisected
- A3: One lymph node bisected
- A4-5: 4 lymph nodes each
- A 6: 3 lymph nodes
- A7-8: 4 lymph nodes each

B. The second container is additionally identified as, "right pelvic lymph nodes". Received fresh and placed in formalin is an aggregate of tan-yellow

[page 3 of 4]
tissue measuring 10.5 x 8.5 x 2.0 cm. Fifteen lymph nodes are identified ranging in greatest dimension from 0.2 4.5 cm. The lymph nodes are submitted as follows:

B1-2: Largest lymph node
B3: One lymph node
B4: One lymph node bisected
B5: One lymph node
B6-7: One lymph node
B8: 3 lymph nodes
B9: 2 lymph nodes
B10: 5 lymph nodes

C. The third container is additionally identified as, "bladder, prostate, seminal vesicles, vas deferens". Received fresh and placed in formalin is a 21 x 11 x 5.5 cm cystoprostatectomy specimen consisting of a 9.5 x 8.5 x 5.0 cm bladder with attached mesenteric fat and a 4.2 x 3.8 x 3.0 cm prostate. The right seminal vesicles measure 3.0 x 1.5 x 0.5 cm and right vas deferens measures 6.0 cm. The left seminal vesicles measures 2.8 x 1.5 x 0.6 cm and left vas deferens measures 6.5 cm. The right ureteral stump measures 0.5 cm in length and is dilated up to 0.9 cm in diameter, the left measures 0.6 cm in length and has a 0.1 cm diameter, and both demonstrate intact, patent lumens.

The right half of the prostate is inked blue and the left half is inked black. The bladder is inked black. The bladder and prostate are opened anteriorly along the urethra. The prostate is surrounded by a thin, intact membranous capsule and sectioning demonstrates rubbery, pink-tan, peri-urethral nodularity with no discrete masses or indurations.

The opened bladder reveals a 4.0 x 3.5 x 1.0 cm firm, tan mass located in the right lateral wall extending posteriorly and anteriorly. On cut section, the mass grossly extends through the mucosa and is 1.8 cm from the deep margin. The surrounding bladder mucosa is edematous, wrinkled, and pink-tan with a 1.0 1.5 cm wall thickness. Bilateral ureteral orifices, adjacent to the trigone, are identified and probe patent. Two lymph node candidates are identified in the perivesicular adipose tissue measuring 0.4 cm and 0.6 cm.

Representative sections are submitted as follows:

C1: Distal prostatic urethral margin (apex)
C2: Right ureter resection margin
C3: Left ureter resection margin
C4: Prostate apex serially sectioned
C5-10: Bladder mass, postero-lateral (C6-7, C9-10 in tandem)
C11: Uninvolved bladder mucosa bladder dome
C12: Uninvolved bladder mucosa posterior wall
C13-14: Bladder mass, antero-lateral

[page 4 of 4]
C15: Uninvolved bladder mucosa anterior wall

C16-18: Representative right lobe of prostate from apex to base

C19-21: Representative left lobe of prostate submitted from apex to base

C22: 2 lymph node candidates

D. The fourth container is additionally identified as, "right distal ureter".

Received fresh and placed in formalin is an unoriented piece of detached tan tissue with attached yellow adipose consistent with ureter measuring 2.5 cm in length diameter of 0.9 cm. The specimen is entirely submitted in D1-2.

E. The fifth container is additionally identified as, "bilateral vas deferens".

Received fresh and placed in formalin are 2 unoriented pieces of pink to tan tissue consistent with vas deferens. The first measures 0.5 cm in length with a diameter of 0.4 cm. The second measures 4.5 cm in length with a diameter of 0.4 cm. Representative sections are submitted in E1.

Source: NCI Genomic Data Commons file 73035bde-dda3-42b9-947e-704584d82936 (TCGA-FD-A43N.1F3E42FB-862D-4B8C-BAC0-9B69011D28F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).